Surgical pathology report (de-identified scan), TCGA case TCGA-18-3421, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-3421-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Lymph-Node: ST12R Lobar
2. Lymph node: Interlobar ST11
3. LUNG:

AGNOSIS

1. Lymph-Node, lobar ST12R, biopsy:
- Negative for malignancy, lymph node with follicular lymphoid hyperplasia.
2. Lymph node, interlobar ST11, biopsy:
- Negative for malignancy, lymph nodes with follicular lymphoid hyperplasia
3. Lung, right lower lobe, lobectomy:
- Squamous cell carcinoma, moderately differentiated with prominent necrosis:
- Maximal tumour size: 7.7cm
- Visceral pleura invasion present
- Surgical resection margins negative for malignancy
- All peribronchial lymph nodes (6 lobar and 1 segmental) negative for malignancy (x 7)
- Remaining lung parenchyma shows mild centroacinar emphysema and focal non-specific pneumonitis.

SYNOPTIC DATA

Specimen Type:	Lobectomy
Laterality:	Right
Tumor Site:	RLL
Tumor Size:	Greatest dimension: 7.7 cm
	Additional dimensions: 7.5 x 7.0 cm

[page 2 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G2: Moderately differentiated
Pathologic Staging (pTNM):	pT2: Tumor with any of the following
features of size or extent:	greater than 3 cm in greatest dimension;
involves main bronchus,	2 cm or more distal to the carina; invades the
visceral pleura; associated with atelectasis or obstructive pneumonitis	that extends to the hilar region but does not involve the entire lung
	pN0: No regional lymph node
metastasis	
	pMX: Cannot be assessed
Margins:	Margins uninvolved by invasive
carcinoma	
	Distance of invasive carcinoma from
closest margin: 3.5 cm	
	Margin: (bronchial resection margin)
Direct Extension of Tumor:	Visceral pleura
Blood Vessel Invasion:	Absent
Additional Pathologic Findings:	Inflammation (type): focal chronic
interstitial inflammation and fibrosis	of undetermined significance
	Slight centrilobular emphysema

[REDACTED]

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "ST 12R".
Lymph nodes: Multiple lymph nodes ranging from 0.3 to 0.8 cm in greatest dimension are identified, and are submitted in toto for frozen section.
1A-1B frozen section block the resubmitted
2. The specimen is labeled with the patient's identification and as "interlobar ST11".
Lymph nodes: Multiple lymph nodes ranging from 0.3 x 0.3 x 0.2 to 1.2 x 1.2 to 0.3 cm are identified, and are submitted in toto as follows:
2A nodes

The specimen is labeled with the patient's name and as "right lower

[page 3 of 3]
lobe ".

Resection specimen: Right lung lobectomy measuring 19 x 14 x 8cm.

Pleural surface: intact, shows surface adhesions, has an area of puckering measuring 7 x 3.5cm.

Number of tumours: 1

Measurements: 7.5 x 7.7 x 7.0cm.

Location: peripheral

Distance from resection margins:

3.5 cm from the bronchial resection margin

4.5 cm from the closest stapled parenchymal resection margin.

Descriptive characteristics: Tan to white in colour; solid and partly friable in consistency; well delineated

lung parenchyma: mildly emphysematous

Lymph Nodes: Multiple peribronchial lymph nodes are identified up to 1.3 cm in greatest dimension.

Frozen Section: Yes

Tissue Banking: Yes

Representative sections are submitted as follows:

3A bronchial margin

3B staple line margin

3C 4 peribronchial nodes

3D one peribronchial node bisected

3E one peribronchial node bisected

3F-3I tumor

3J-3K normal lung

3L one segmental node bisected

1A, 1B - Lymph nodes, negative for malignancy. Reported to
1358h.

Source: NCI Genomic Data Commons file 38134687-140a-4ab3-96e9-0ce7cac418e4 (TCGA-18-3421.7640A498-7B8B-4E83-959D-C87E6753E12C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).